Somatic mutation profile of tumor specimen HTMCP-03-06-02188-01A (aliquot HTMCP-03-06-02188-01A-01D-6194) from CGCI case HTMCP-03-06-02188, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G3.
Specimen HTMCP-03-06-02188-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 643363d4-fb5b-49ac-af1c-af0db86049d0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02188-10A (Blood Derived Normal), aliquot HTMCP-03-06-02188-10A-01D-6194; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbf29701-664b-4f37-8348-0c5ec8d3e4f2

The open-access MAF lists 38 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 26, Silent 7, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP2 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367900188; called by muse, mutect2, varscan2
- ALK | c.2635G>A p.G879S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs573634420, COSV66564190; called by muse, mutect2, varscan2
- ARHGAP45 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.454); catalogued as rs941777758; called by muse, varscan2
- ARMC4 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV53462469, COSV53465241; called by muse, mutect2, varscan2
- C6 | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.899); catalogued as COSV54709179; called by muse, mutect2, varscan2
- CDCA5 | c.208-4G>A | Splice Region (SNP) | VAF 18/61 reads (30%) | catalogued as rs1205028087; called by muse, mutect2, varscan2
- CHD3 | c.3724G>A p.E1242K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs766775771; called by muse, mutect2, varscan2
- CYLD | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as COSV61093931; called by muse, mutect2, varscan2
- DCHS1 | c.8381C>T p.S2794L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55000222; called by muse, mutect2, varscan2
- HFM1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.162); catalogued as rs202217676, COSV54025491; called by muse, mutect2, varscan2
- ITIH2 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100623240, COSV64435503; called by muse, mutect2, varscan2
- KDM6A | c.3397C>T p.Q1133* | Nonsense Mutation (SNP) | VAF 43/72 reads (60%) | catalogued as COSV65036907; called by muse, mutect2, varscan2
- KIFC3 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs782658841, COSV65548938; called by muse, mutect2, varscan2
- NLGN1 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 92/466 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64345717; called by muse, mutect2, varscan2
- SULF1 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs1448775704, COSV52693822; called by muse, mutect2, varscan2
- TLR7 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.619); catalogued as COSV101028234; called by muse, mutect2, varscan2
- TTN | c.26125G>A p.D8709N (on ENST00000591111; = p.D7782N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/170 reads (35%) | PolyPhen benign (0.033); catalogued as COSV100627072; called by muse, mutect2, varscan2
- WDR87 | c.5238G>C p.K1746N | Missense Mutation (SNP) | VAF 123/333 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.617); catalogued as COSV58195354; called by muse, mutect2, varscan2
- ZFYVE16 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100566313; called by muse, mutect2, varscan2
- ANKS1B | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ARHGEF6 | c.2136G>T p.K712N | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GOLGA6L2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KIF2C | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- LYST | c.2815C>T p.H939Y | Missense Mutation (SNP) | VAF 147/384 reads (38%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MACF1 | c.20644G>A p.E6882K (on ENST00000372915; = p.E4927K on NM_012090.5) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- MMP20 | c.204G>T p.M68I | Missense Mutation (SNP) | VAF 234/424 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- OVCH1 | c.158C>A p.S53* | Nonsense Mutation (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- PCM1 | c.4441del p.T1481Pfs*4 | Frame Shift Del (DEL) | VAF 44/144 reads (31%) | called by mutect2, pindel, varscan2
- SLC9C1 | c.2650-2A>G p.X884_splice | Splice Site (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.4727A>C p.N1576T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- TRPM7 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CPED1 | c.381C>T p.V127= | Silent (SNP) | VAF 11/242 reads (5%) | called by muse, mutect2
- DOCK4 | c.375G>A p.L125= | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as COSV101455501; called by muse, mutect2, varscan2
- DST | c.3465G>A p.Q1155= (on ENST00000361203 / NM_001374722.1; = p.Q829= on NM_001723.6) | Silent (SNP) | VAF 124/216 reads (57%) | called by muse, mutect2, varscan2
- KIF20B | c.514C>T p.L172= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs769831424, COSV53306611; called by muse, mutect2, varscan2
- PDE4DIP | c.3246G>A p.V1082= | Silent (SNP) | VAF 85/245 reads (35%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.1713C>T p.L571= | Silent (SNP) | VAF 64/184 reads (35%) | called by mutect2, varscan2
- TMC1 | c.381G>T p.V127= | Silent (SNP) | VAF 44/171 reads (26%) | called by muse, mutect2, varscan2
